Surgical pathology report (de-identified scan), TCGA case TCGA-K1-A6RT, project TCGA-SARC (Sarcoma), tissue source site University of Pittsburgh, specimen TCGA-K1-A6RT-01A (Primary Tumor).

ICD-0-3

Leiomyosarcoma NOS
8890/3

Site: Soft tissue of
① thigh C49.2
Gw 8/2/13

Collection Date:

FINAL DIAGNOSIS:

SOFT TISSUE, RIGHT THIGH, WIDE EXCISION -

- A. RESIDUAL LEIOMYOSARCOMA, INTERMEDIATE GRADE (see comment).
- B. MITOSES: 12 PER 10/HPF; NO NECROSIS SEEN.
- C. SCAR WITH SKELETAL MUSCLE ATROPHY, FAT NECROSIS AND FOREIGN BODY GIANT CELL REACTION, (PREVIOUS SURGICAL SITE).
- D. RESECTION MARGINS FREE OF TUMOR.

COMMENT:

The neoplasm is morphologically similar to that in the previous surgical specimen [REDACTED]

Source: NCI Genomic Data Commons file d479c279-38bb-492e-8aea-86fca35be8df (TCGA-K1-A6RT.B530297E-CC48-4363-9497-92F4BA3E875C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).